Somatic mutation profile of tumor specimen C3N-04282-01 (aliquot CPT0246990006) from CPTAC case C3N-04282, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 75.8 years (27,699 days).
Specimen C3N-04282-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a0e7797-c14c-4471-8eda-3107113456a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04282-31 (Blood Derived Normal), aliquot CPT0247030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e76228c-bb3d-49d4-b65a-11dfb75da943

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 6, 5'Flank 3, Frame Shift Del 3, Intron 2, Splice Site 2, Splice Region 2, Nonsense Mutation 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 171/384 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 326/1107 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1209439378; called by muse, mutect2, varscan2
- AL136295.1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759491065, COSV55778221; called by muse, mutect2, varscan2
- AMOTL2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 266/1014 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs756431790, COSV51440152; called by muse, mutect2, varscan2
- ARHGAP4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 125/208 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs142621606, COSV63131159; called by muse, mutect2, varscan2
- C10orf90 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 131/657 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs756021619, COSV99504737; called by muse, mutect2, varscan2
- EFTUD2 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs376157050, COSV101274556, COSV68182821; called by muse, mutect2
- EP300 | c.3842G>T p.R1281L | Missense Mutation (SNP) | VAF 92/256 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as COSV54330185, COSV99607677; called by muse, mutect2, varscan2
- FAM184B | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53958874, COSV99034700; called by muse, mutect2, varscan2
- GALR2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 126/499 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs902808127, COSV57162907; called by muse, mutect2, varscan2
- GPR143 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs62635289, CM003022; ClinVar: not provided; called by muse, mutect2, varscan2
- KCNB2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 108/331 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs770363006, COSV73050496; called by muse, mutect2, varscan2
- KIR2DL4 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 329/574 reads (57%) | catalogued as rs1293783810, COSV60878136; called by muse, mutect2, varscan2
- LHCGR | c.32_52del p.L11_L17del | In Frame Del (DEL) | VAF 66/438 reads (15%) | catalogued as rs745332851; called by pindel, varscan2
- LINGO1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 126/505 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.88); catalogued as rs758132909, COSV62438690; called by muse, mutect2, varscan2
- LUC7L2 | c.727C>G p.R243G | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV54928619; called by muse, varscan2
- MEGF8 | c.2230G>A p.V744M | Missense Mutation (SNP) | VAF 143/267 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs1015184528; called by muse, mutect2, varscan2
- MGAM2 | c.4003G>A p.V1335I | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs937654142, COSV72176648; called by muse, mutect2, varscan2
- OR5M3 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs769048277; called by muse, mutect2, varscan2
- PLXNB2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 121/310 reads (39%) | catalogued as rs1333488993, COSV63780558; called by muse, mutect2, varscan2
- SCN4A | c.393-1C>T p.X131_splice | Splice Site (SNP) | VAF 42/259 reads (16%) | catalogued as rs1199378574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2B1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs751235771, COSV59466817; called by muse, mutect2, varscan2
- SLIT2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.589); catalogued as rs749945090; called by muse, mutect2, varscan2
- SNRNP200 | c.4942C>T p.R1648W | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs377595031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK40 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 105/564 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.068); catalogued as rs200773119, COSV63735707; called by muse, mutect2, varscan2
- ARID2 | c.1094del p.S365* | Frame Shift Del (DEL) | VAF 46/125 reads (37%) | called by mutect2, pindel, varscan2
- C3orf52 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHPF | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 73/398 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ENC1 | c.143T>A p.V48D | Missense Mutation (SNP) | VAF 136/502 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- FAM117B | c.847-16_856del p.X283_splice | Splice Site (DEL) | VAF 71/276 reads (26%) | called by mutect2, pindel, varscan2
- HDAC6 | c.3637C>T p.H1213Y | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LRRC37B | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 214/538 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRC40 | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- NDUFAF3 | c.438G>T p.T146= | Splice Region (SNP) | VAF 180/651 reads (28%) | called by muse, mutect2, varscan2
- NPEPL1 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCDHGA1 | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- POLE | c.910-5G>T | Splice Region (SNP) | VAF 181/417 reads (43%) | called by muse, mutect2, varscan2
- RBBP6 | c.711del p.F238Sfs*29 | Frame Shift Del (DEL) | VAF 46/168 reads (27%) | called by mutect2, pindel, varscan2
- RNF43 | c.770del p.G257Vfs*162 | Frame Shift Del (DEL) | VAF 70/335 reads (21%) | called by mutect2, pindel, varscan2
- TTI2 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 202/613 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- FKRP | c.1275C>T p.G425= | Silent (SNP) | VAF 625/1104 reads (57%) | catalogued as rs1324549932; called by muse, mutect2, varscan2
- LRRK2 | c.2148G>A p.A716= | Silent (SNP) | VAF 236/505 reads (47%) | catalogued as rs200459681; called by muse, mutect2, varscan2
- POTEE | c.2769C>T p.F923= | Silent (SNP) | VAF 251/3139 reads (8%) | catalogued as rs745389252, COSV58226044, COSV58228074; called by muse, mutect2
- PPA2 | c.78C>G p.T26= | Silent (SNP) | VAF 46/322 reads (14%) | called by muse, mutect2, varscan2
- PRKCQ | c.66C>T p.G22= | Silent (SNP) | VAF 117/401 reads (29%) | catalogued as rs762275564; called by muse, mutect2, varscan2
- TBX20 | c.231C>T p.S77= | Silent (SNP) | VAF 129/483 reads (27%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822783 G>A | 5'Flank (SNP) | VAF 55/101 reads (54%) | called by muse, mutect2, varscan2
- HIVEP1 | c.40+4726G>A | Intron (SNP) | VAF 137/362 reads (38%) | called by muse, mutect2, varscan2
- MIR323A | n.50G>A | RNA (SNP) | VAF 124/402 reads (31%) | catalogued as rs762957686; called by muse, mutect2, varscan2
- SGCE | chr7:94656121 G>C | 5'Flank (SNP) | VAF 141/518 reads (27%) | called by muse, mutect2, varscan2
- SGIP1 | c.1571-967A>G | Intron (SNP) | VAF 36/190 reads (19%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439694 C>T | 5'Flank (SNP) | VAF 12/306 reads (4%) | catalogued as rs1201597748; called by muse, mutect2
